Surgical pathology report (de-identified scan), TCGA case TCGA-UE-A6QU, project TCGA-SARC (Sarcoma), tissue source site  Asterand, specimen TCGA-UE-A6QU-01A (Primary Tumor).

[page 1 of 2]
Patient ID:

Surgical Date:

Gross Description: In Soft tissue, right shoulder, There is a large lobulated mass. They are encapsulated, with 16x12x10cm in size, solid, yellow, myxoid and gray surface.

Microscopic Description: Tumor is heterogenous and composed of sheets or trabeculae or nodules. The majority of cell tumours are spindle. Tumour is moderate cellularity. Tumour has in marked cytological and nuclear pleomorphism, with spindle or oval in shape, single or multiple nuclei. Cytoplasm are eosinophilic and scant and vascularized containing lipid. Nuclei are hyperchromatic and very irregular with prominent nucleoli. Mitosis are present. Tumor is myxoid change

Diagnosis Details: Pleomorphic Liposarcoma

Comments:

Formatted Path Reports: Tumor site: Soft tissue, shoulder

Tumor size (in cm): 16x12x10cm

Histologic type: Pleomorphic Liposarcoma

Histologic grade: Poorly differentiated

Tumor extent:

Lymph nodes:

Margins: uninvolved

Evidence of neo-adjuvant treatment:

If yes, type of treatment seen:

Severity of treatment effect:

Comments:

ICD-O-3

Liposarcoma, pleomorphic 8854/3

Site ^{P. 16x12x10cm} Extremities NOS C49.2

^{path} Soft tissue of shoulder C49.1

JA 17/5/13

Criteria	11/7/13	Pathologist	Yes	No
Diagnosis Discrepancy		Pathologist	✓	
Case is (circled)				

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name) _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	De-differentiated Liposarcoma (poorly)	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Pleomorphic Liposarcoma	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Slides	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 63802d56-5f06-4a4d-aa84-8472d5f270d8 (TCGA-UE-A6QU.24A5EEC3-59D2-4B2E-A165-34410778E6CB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).